Somatic mutation profile of tumor specimen C3N-01537-01 (aliquot CPT0097010009) from CPTAC case C3N-01537, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage II; FIGO stage: Stage II; Tumor grade: G3; Age at diagnosis: 74.8 years (27,304 days).
Specimen C3N-01537-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aded1c2d-2cdc-4a34-8c1f-893fc479755a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01537-31 (Blood Derived Normal), aliquot CPT0097050002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/36fb4b34-a7bb-4b6c-a713-c83e815b73cf

The open-access MAF lists 52 somatic variants for this specimen: 38 protein-altering or splice-affecting, 10 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 10, Frame Shift Del 4, In Frame Del 2, Intron 2, Nonsense Mutation 1, Splice Site 1, Splice Region 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1678G>T p.D560Y (on ENST00000521381 / NM_181523.3; = p.D290Y on NM_181504.4) | Missense Mutation (SNP) | VAF 52/238 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1057519839, COSV57123942, COSV57127598, COSV57130158; ClinVar: likely pathogenic; called by muse, varscan2
- ABCF1 | c.1160G>A p.R387Q (on ENST00000326195 / NM_001025091.2; = p.R349Q on NM_001090.3) | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.49); catalogued as rs866488428; called by muse, mutect2
- FRMPD4 | c.2182G>A p.A728T | Missense Mutation (SNP) | VAF 32/432 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs750615873, COSV66214605; ClinVar: uncertain significance; called by muse, mutect2
- HOXC13 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.443); catalogued as rs1321134788; called by muse, mutect2, varscan2
- KMT2A | c.9833C>G p.S3278C | Missense Mutation (SNP) | VAF 75/267 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.817); catalogued as COSV100627590; called by muse, mutect2, varscan2
- LIPF | c.1004T>C p.I335T | Missense Mutation (SNP) | VAF 59/397 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs767622980; called by muse, mutect2, varscan2
- METTL3 | c.1518+1G>T p.X506_splice | Splice Site (SNP) | VAF 91/353 reads (26%) | catalogued as COSV52969092; called by muse, mutect2, varscan2
- MNT | c.805del p.Q269Sfs*3 | Frame Shift Del (DEL) | VAF 64/206 reads (31%) | catalogued as COSV99438040; called by mutect2, pindel, varscan2
- MUC3A | c.7421C>T p.P2474L | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT deleterious, low confidence (0.04); catalogued as rs1167516550; called by muse, mutect2, varscan2
- PIK3R1 | c.1636G>T p.E546* (on ENST00000521381 / NM_181523.3; = p.E276* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 48/232 reads (21%) | catalogued as COSV57125309, COSV57130430; called by muse, varscan2
- PRM2 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 49/562 reads (9%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.006); catalogued as rs201640369, COSV54112831; called by muse, mutect2
- SS18L1 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 15/327 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.646); catalogued as rs1429681898; called by muse, mutect2
- SV2A | c.1957G>A p.A653T | Missense Mutation (SNP) | VAF 30/388 reads (8%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.773); catalogued as rs782742097, COSV64964535; called by muse, mutect2
- SVOP | c.1057C>T p.R353W | Missense Mutation (SNP) | VAF 69/367 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs764499042, COSV54468848; called by muse, mutect2, varscan2
- TNR | c.1400C>T p.T467M | Missense Mutation (SNP) | VAF 41/301 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs753755790; called by muse, mutect2, varscan2
- TTC38 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 64/180 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1158809608; called by muse, mutect2, varscan2
- UBR5 | c.67C>G p.R23G | Missense Mutation (SNP) | VAF 43/207 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV55279851; called by muse, mutect2, varscan2
- ZP2 | c.1681G>A p.V561I | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs781257839; called by muse, varscan2
- ALDH1L1 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ARHGAP35 | c.264del p.E88Dfs*83 | Frame Shift Del (DEL) | VAF 85/369 reads (23%) | called by mutect2, pindel, varscan2
- BRSK2 | c.1010T>C p.L337P | Missense Mutation (SNP) | VAF 14/320 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CADM2 | c.202_204del p.D68del (on ENST00000407528 / NM_001167674.2; = p.D70del on NM_153184.4) | In Frame Del (DEL) | VAF 33/153 reads (22%) | called by pindel, varscan2
- CEP85 | c.541A>C p.I181L | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.012); called by muse, mutect2
- DNAJA4 | c.315C>G p.G105= (on ENST00000343789; = p.G134= on NM_018602.3) | Splice Region (SNP) | VAF 41/177 reads (23%) | called by muse, mutect2
- FBXW7 | c.799del p.H267Ifs*2 (on ENST00000281708 / NM_001349798.2; = p.H187Ifs*2 on NM_018315.5) | Frame Shift Del (DEL) | VAF 31/183 reads (17%) | called by mutect2, pindel, varscan2
- FOS | c.810_812del p.D271del | In Frame Del (DEL) | VAF 120/660 reads (18%) | called by pindel, varscan2
- INTS13 | c.1208G>A p.S403N | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- IPO7 | c.2943_2946del p.H982Vfs*13 | Frame Shift Del (DEL) | VAF 32/231 reads (14%) | called by mutect2, pindel, varscan2
- KALRN | c.8059C>A p.L2687M (on ENST00000360013 / NM_001024660.4; = p.L990M on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/221 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- MEFV | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- MYH15 | c.4283G>A p.R1428K | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- NCAPD2 | c.1808C>T p.S603L | Missense Mutation (SNP) | VAF 70/360 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- NEXMIF | c.2438G>A p.G813E | Missense Mutation (SNP) | VAF 39/298 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIK3R2 | c.1664A>T p.E555V | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PLXNA3 | c.4645A>G p.T1549A | Missense Mutation (SNP) | VAF 15/155 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- ZFHX4 | c.3777G>A p.M1259I | Missense Mutation (SNP) | VAF 33/444 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- ZNF583 | c.1339A>C p.N447H | Missense Mutation (SNP) | VAF 8/213 reads (4%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.993); called by muse, mutect2
- ZNF621 | c.566A>G p.K189R | Missense Mutation (SNP) | VAF 17/443 reads (4%) | SIFT tolerated (0.53); PolyPhen benign (0.01); called by muse, mutect2
- ADGRG4 | c.5910C>T p.D1970= | Silent (SNP) | VAF 34/236 reads (14%) | catalogued as rs760543724, COSV54949082; called by muse, mutect2, varscan2
- DQX1 | c.1413C>T p.A471= | Silent (SNP) | VAF 14/280 reads (5%) | called by muse, mutect2
- FUT11 | c.177G>A p.T59= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs1418338523; called by muse, mutect2, varscan2
- IL20RA | c.312C>T p.Y104= | Silent (SNP) | VAF 35/185 reads (19%) | catalogued as rs771466183; called by muse, mutect2, varscan2
- KIT | c.591G>A p.S197= | Silent (SNP) | VAF 28/415 reads (7%) | catalogued as rs140839561; ClinVar: likely benign; called by muse, mutect2
- MKRN1 | c.1371C>T p.D457= | Silent (SNP) | VAF 75/621 reads (12%) | catalogued as rs374563168; called by muse, mutect2, varscan2
- PCNT | c.7224G>A p.A2408= | Silent (SNP) | VAF 137/477 reads (29%) | catalogued as rs140912550; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCX | c.579C>G p.R193= | Silent (SNP) | VAF 32/386 reads (8%) | called by muse, mutect2
- SON | c.330G>A p.K110= | Silent (SNP) | VAF 13/107 reads (12%) | called by muse, varscan2
- TTN | c.25518G>A p.T8506= (on ENST00000591111; = p.T7579= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/114 reads (11%) | catalogued as rs775381639, COSV100627707; called by mutect2, varscan2
- MGAT5B | c.69-24G>A | Intron (SNP) | VAF 132/440 reads (30%) | called by muse, mutect2, varscan2
- SSX6P | n.74C>T | RNA (SNP) | VAF 26/236 reads (11%) | catalogued as rs150874433; called by muse, mutect2
- TRAPPC10 | c.791-483G>A | Intron (SNP) | VAF 51/298 reads (17%) | called by muse, mutect2, varscan2
- ZNF747 | c.*416C>T | 3'UTR (SNP) | VAF 28/195 reads (14%) | called by muse, mutect2, varscan2
